Somatic mutation profile of tumor specimen 0DXJI2 from CCDI case PBCRMF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.3 years (7,060 days).
Specimen 0DXJI2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 877aa0a0-3678-4444-8324-316b7570cea8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXJEM (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b58aca01-c0ec-4243-9637-e6150fb1f570

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR1 | c.1638C>A p.N546K (on ENST00000447712 / NM_023110.3; = p.N544K on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 205/964 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779707422, COSV58329537, COSV58330551; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 450/1965 reads (23%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDF1 | c.583C>A p.P195T | Missense Mutation (SNP) | VAF 203/829 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.288); catalogued as COSV57670942; called by muse, varscan2
- MYT1L | c.25C>T p.R9W | Missense Mutation (SNP) | VAF 228/1126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759537467, COSV67731013; called by muse, mutect2, varscan2
- CD46 | c.1164A>T p.K388N | Missense Mutation (SNP) | VAF 50/1917 reads (3%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.007); called by muse, mutect2
- UGT1A4 | c.508G>C p.V170L | Missense Mutation (SNP) | VAF 355/1818 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YIF1B | c.121G>A p.D41N (on ENST00000339413 / NM_001039673.3; = p.D26N on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/1038 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- IGSF1 | c.667+118A>G | Intron (SNP) | VAF 70/183 reads (38%) | called by muse, mutect2, varscan2
- PRTFDC1 | c.48+76_48+79del | Intron (DEL) | VAF 83/365 reads (23%) | called by mutect2, pindel, varscan2
